Surgical pathology report (de-identified scan), TCGA case TCGA-SC-AA5Z, project TCGA-MESO (Mesothelioma), tissue source site Memorial Sloan Kettering, specimen TCGA-SC-AA5Z-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: [REDACTED]
Account #: [REDACTED] Date of Procedure: [REDACTED]
DOB: [REDACTED] (Age: M Date of Receipt: [REDACTED]
Physician: [REDACTED] Date of Report: [REDACTED]
CC: [REDACTED]
Patient Address: [REDACTED]

....

Clinical Diagnosis & History:

History of renal cell carcinoma, never smoker but positive second hand, no asbestos exposure, recurrent left pleural effusion with pleural thickening on imaging

Specimens Submitted:

- 1: Left pleura biopsy (fs)
- 2: Additional left pleural biopsy

DIAGNOSIS:

1. Left pleura biopsy (fs):
- Malignant mesothelioma, epitheloid type; see note

Note: Immunohistochemistry demonstrates that tumor cells are positive for calretinin, AE1/AE3 and WT1, while they are negative for CD15, PAX8, BerEp4 and CEA.

2. Additional left pleural biopsy:
- Malignant mesothelioma, epitheloid type; see note

Note: Immunohistochemistry demonstrates that tumor cells are positive for calretinin, while they are negative for PAX8.

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88) as qualified to perform high complexity clinical laboratory testing.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

** Continued on next page **

ICD O-3

Mesothelioma, epitheloid,
malignant 9052/3
Site @ Pleura NOS Q38.4
9/3/12/14

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Patient:

MRN:

Account

Accession #: [REDACTED]

Physician:

Service: Thoracic

Date of Report:

Page 2 of 3

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh for frozen section consultation, labeled "left pleural biopsy" and consists of multiple fragments of membranous and nodular tissue measuring 2.8 x 2.1 x 0.4 cm in aggregate. Specimen is entirely submitted for frozen section.

Summary of sections:

FSC -- frozen section control

2) The specimen is received fresh, labeled "Additional left pleural biopsy", and consists of a 3.0 x 2.5 x 0.4 cm aggregate of tan-pink fibromembranous tissue. The specimen is entirely submitted.

Summary of sections:

U-undesignated

Summary of Sections:

Part 1: Left pleura biopsy (fs)

Block	Sect.	Site	PCs	
1		FSC		10

Part 2: Additional left pleural biopsy

Block	Sect.	Site	PCs	
1		U		1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen Section Diagnosis: Left pleura biopsy (fs): Epithelioid neoplasm defer to permanents for further classification; differential includes mesothelioma

Permanent Diagnosis: Same

2. Frozen Section Diagnosis: 2. Additional left pleural biopsy (fs): Per submitting clinician, no frozen is performed

Permanent Diagnosis: Same

** Continued on next page **

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Patient:

MRN:

Account #:

Accession #:

Physician:

Service: Thoracic

Date of Report:

Page 3 of 3

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen Section Diagnosis: Left pleura biopsy (fs): Epithelioid neoplasm defer to permanents for further classification; differential includes mesothelioma

Permanent Diagnosis: Same

2. Frozen Section Diagnosis: 2. Additional left pleural biopsy (fs): Per submitting clinician, no frozen is performed

Permanent Diagnosis: Same

** End of Report **

Source: NCI Genomic Data Commons file a3191740-856d-4644-a637-2282b304dbe2 (TCGA-SC-AA5Z.6510EC39-20FA-40AB-B640-7E02E98F3FC7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).